Somatic mutation profile of tumor specimen TCGA-WA-A7H4-01A (aliquot TCGA-WA-A7H4-01A-21D-A34J-08) from TCGA case TCGA-WA-A7H4, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 69.4 years (25,363 days).
Specimen TCGA-WA-A7H4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db2f6002-16b3-4f6f-8978-51b6287ed01b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WA-A7H4-10A (Blood Derived Normal), aliquot TCGA-WA-A7H4-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ee5e5fd-34b8-4209-8304-a41a7ec33a86

The open-access MAF lists 61 somatic variants for this specimen: 50 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 48, Silent 11, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARAP2 | c.1702A>G p.I568V | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs199846587, COSV100394454; called by muse, mutect2, varscan2
- CCDC18 | c.1725G>C p.K575N (on ENST00000343253 / NM_001306076.1; = p.K576N on NM_206886.4) | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100159458; called by muse, mutect2
- CDK12 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.253); catalogued as rs1423075897, COSV101420426; called by muse, mutect2
- CENPQ | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs767389861, COSV100225636; called by muse, mutect2, varscan2
- COBLL1 | c.2279A>T p.D760V (on ENST00000392717; = p.D722V on NM_014900.5) | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.02); catalogued as COSV99527727, COSV99527747; called by muse, mutect2, varscan2
- DCLK2 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 17/185 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV99651789; called by muse, mutect2
- EIF4A2 | c.979C>G p.L327V | Missense Mutation (SNP) | VAF 25/262 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99961154; called by muse, mutect2
- EPHA5 | c.409T>G p.C137G | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV99898181; called by muse, mutect2
- FBXL5 | c.1243C>G p.Q415E | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs1246974106, COSV100377837; called by muse, mutect2
- FMN2 | c.1220G>A p.C407Y | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs1208058321, COSV100144582; called by mutect2, varscan2
- G6PD | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100855009; called by muse, mutect2, varscan2
- GAN | c.1055A>G p.N352S | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs779203584, COSV101633976; called by muse, mutect2, varscan2
- GIPC3 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100461244; called by muse, mutect2
- GLI2 | c.3403G>A p.G1135S (on ENST00000361492 / NM_001374353.1; = p.G1152S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58036642; called by muse, mutect2, varscan2
- GMIP | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99179168; called by muse, mutect2
- KALRN | c.1418A>G p.Q473R | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.98); catalogued as COSV99563600; called by muse, mutect2, varscan2
- KCTD20 | c.571G>C p.D191H | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV54804302; called by muse, mutect2
- KLF7 | c.664C>G p.Q222E | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.306); catalogued as COSV100519086; called by muse, mutect2, varscan2
- KXD1 | c.50G>T p.S17I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV99723657; called by muse, mutect2
- LAPTM4A | c.382A>G p.I128V | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as rs760722103, COSV99442329; called by muse, mutect2, varscan2
- LPIN2 | c.2055C>G p.I685M | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV99858268; called by muse, mutect2, varscan2
- LRRC37B | c.964C>G p.H322D | Missense Mutation (SNP) | VAF 11/214 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.198); catalogued as COSV100496192; called by muse, mutect2
- MAG | c.1782C>A p.D594E | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs200067189, COSV100727729; called by muse, mutect2, varscan2
- N4BP1 | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.307); catalogued as COSV99285066; called by muse, mutect2, varscan2
- NOM1 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.173); catalogued as COSV51982386, COSV99315627; called by muse, mutect2
- OBSCN | c.10443G>C p.W3481C | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99475697, COSV99476589; called by muse, mutect2
- OR2T2 | c.687G>A p.M229I | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as COSV61618706; called by muse, mutect2
- PCDHAC1 | c.1730G>T p.G577V | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99165808; called by muse, mutect2, varscan2
- PCNT | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs760977293, COSV99387999; called by muse, mutect2
- PLA2G4F | c.1766G>A p.S589N | Missense Mutation (SNP) | VAF 17/254 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.326); catalogued as COSV99300554; called by muse, mutect2
- PRKCH | c.674A>G p.Q225R | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV100273177; called by muse, mutect2
- QDPR | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.757); catalogued as rs1003019570, COSV99845791; called by muse, mutect2
- RDH10 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.47); catalogued as rs754396419, COSV99536267; called by muse, mutect2
- RNASE2 | c.324C>G p.I108M | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs1215690622, COSV100482043, COSV58940896; called by muse, mutect2, varscan2
- RNASE2 | c.325C>T p.H109Y | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1258122120, COSV100482044, COSV100482090; called by muse, mutect2, varscan2
- RPA2 | c.292A>G p.T98A | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100536153; called by muse, mutect2, varscan2
- SCN3B | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs147803210, CM109584, COSV54800502; called by muse, mutect2, varscan2
- SLF1 | c.1916G>C p.R639T | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV99475814; called by muse, mutect2
- STAG1 | c.1360A>G p.R454G | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV99365157; called by muse, mutect2, varscan2
- TAS1R1 | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV100039601; called by muse, mutect2
- TIMELESS | c.2911C>G p.L971V | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.062); catalogued as COSV99973861; called by muse, mutect2
- TTC37 | c.3110A>T p.D1037V | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as rs531584176, COSV100706553; called by muse, mutect2
- USP34 | c.9026G>A p.R3009H | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1226375196, COSV101276917; called by muse, mutect2
- VPS13D | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100692967, COSV62532224; called by muse, mutect2
- ZNF594 | c.560A>G p.E187G | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV101280471; called by muse, mutect2, varscan2
- ZNF709 | c.1660C>G p.H554D | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101172157; called by muse, mutect2
- ZSCAN5B | c.927A>C p.E309D | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.251); catalogued as COSV100627942; called by muse, mutect2
- PHAX | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 16/94 reads (17%) | called by mutect2, pindel, varscan2
- PREX2 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.178); called by muse, mutect2
- TP53 | c.799_807delinsA p.R267Ifs*2 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by pindel, varscan2*
- ADGRL3 | c.1539G>A p.R513= (on ENST00000506720 / NM_001322402.2; = p.R445= on NM_015236.6) | Silent (SNP) | VAF 7/135 reads (5%) | catalogued as COSV72230646; called by muse, mutect2
- ALDOA | c.654C>T p.I218= (on ENST00000642816 / NM_001243177.4; = p.I164= on NM_184041.5) | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as COSV100581973; called by muse, mutect2, varscan2
- ARHGAP5 | c.1767T>C p.D589= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV100565198; called by muse, mutect2, varscan2
- CLPS | c.30C>T p.V10= | Silent (SNP) | VAF 19/202 reads (9%) | catalogued as rs755917684, COSV99463698; called by muse, mutect2
- LARP1 | c.969G>A p.S323= (on ENST00000518297 / NM_033551.3; = p.S246= on NM_015315.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 20/148 reads (14%) | catalogued as rs1021526868, COSV60426235, COSV60426451; called by muse, mutect2, varscan2
- OR6S1 | c.42C>T p.F14= | Silent (SNP) | VAF 15/249 reads (6%) | catalogued as rs747004005, COSV57837515; called by muse, mutect2
- PPM1F | c.1047G>A p.T349= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as rs373995253; called by muse, varscan2
- TACC3 | c.1587T>A p.A529= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as COSV100508649; called by muse, mutect2
- UGT2A1 | c.1338T>A p.I446= | Silent (SNP) | VAF 34/303 reads (11%) | catalogued as COSV99684194; called by muse, mutect2, varscan2
- WASF2 | c.441C>G p.L147= | Silent (SNP) | VAF 26/150 reads (17%) | catalogued as rs200795125, COSV101420759; called by muse, mutect2, varscan2
- ZFHX3 | c.9447G>A p.P3149= | Silent (SNP) | VAF 10/213 reads (5%) | catalogued as rs1236481839, COSV51708181; called by muse, mutect2
